Somatic mutation profile of tumor specimen ALCH-B4XR-TTP1-A (aliquot ALCH-B4XR-TTP1-A-1-0-D-A83F-36) from ALCHEMIST case ALCH-B4XR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 76.7 years (28,010 days).
Specimen ALCH-B4XR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66a2647c-54ed-40c4-8c86-e46a11f7be2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4XR-NB1-A (Blood Derived Normal), aliquot ALCH-B4XR-NB1-A-1-0-D-A83F-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ec222c8-ec93-43bb-9d0f-cdba9487c6ac

The open-access MAF lists 50 somatic variants for this specimen: 34 protein-altering or splice-affecting, 7 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 7, Intron 4, RNA 3, Nonsense Mutation 2, 3'UTR 2, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 110/610 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1345G>A p.G449R | Missense Mutation (SNP) | VAF 69/602 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1131690851, CS071257, COSV57306967; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.833C>G p.P278R | Missense Mutation (SNP) | VAF 124/548 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876659802, CM961376, COSV52661225, COSV52665769, COSV52678063; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AFDN | c.1999G>A p.V667I | Missense Mutation (SNP) | VAF 36/512 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.177); catalogued as rs769690450, COSV60058292; called by muse, mutect2
- CDK3 | c.661_688del p.T221Sfs*111 | Frame Shift Del (DEL) | VAF 41/451 reads (9%) | catalogued as rs767680152; called by mutect2, pindel
- COL12A1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.334); catalogued as COSV59400879; called by muse, mutect2
- CRTAC1 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 43/388 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs546782945, COSV53998548; called by muse, mutect2, varscan2
- MORC1 | c.2278G>T p.D760Y | Missense Mutation (SNP) | VAF 25/257 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV51731292; called by muse, mutect2
- OCRL | c.321C>A p.F107L | Missense Mutation (SNP) | VAF 108/535 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100843556; called by muse, mutect2, varscan2
- PDE10A | c.1211C>G p.S404C | Missense Mutation (SNP) | VAF 14/433 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1405764185; called by muse, mutect2
- PLA1A | c.637G>A p.V213M | Missense Mutation (SNP) | VAF 25/300 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140761557; called by muse, mutect2
- RPL15 | c.25G>T p.E9* | Nonsense Mutation (SNP) | VAF 14/136 reads (10%) | catalogued as COSV57140907; called by muse, mutect2
- SF3B2 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 44/242 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as rs1364459208, COSV59427447; called by muse, mutect2, varscan2
- TRPV5 | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 59/370 reads (16%) | catalogued as rs778703315, COSV54683831; called by muse, mutect2, varscan2
- TUBE1 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 11/242 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as rs201725931; called by muse, mutect2
- ZNF99 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); catalogued as COSV101233942, COSV68054551; called by muse, mutect2
- AK9 | c.3559del p.A1187Qfs*17 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel
- CACNA1S | c.2746C>T p.H916Y | Missense Mutation (SNP) | VAF 25/246 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CLEC2A | c.364C>G p.Q122E | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- COL22A1 | c.3065G>A p.C1022Y | Missense Mutation (SNP) | VAF 148/459 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DDX42 | c.570T>G p.I190M | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- DDX60 | c.1192T>G p.L398V | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2
- GABRG2 | c.581T>G p.L194W | Missense Mutation (SNP) | VAF 30/462 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRIA3 | c.2558A>T p.E853V | Missense Mutation (SNP) | VAF 61/644 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- HYDIN | c.6539C>T p.S2180F | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- MYH7B | c.398T>G p.M133R | Missense Mutation (SNP) | VAF 17/318 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2
- PCF11 | c.1442G>A p.R481K | Missense Mutation (SNP) | VAF 26/353 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.622); called by muse, mutect2
- RPS6KB2 | c.179A>C p.E60A | Missense Mutation (SNP) | VAF 53/328 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- SAXO1 | c.1126G>A p.A376T | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.94); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPTBN5 | c.2046+1G>C p.X682_splice | Splice Site (SNP) | VAF 28/209 reads (13%) | called by muse, mutect2, varscan2
- SSMEM1 | c.341A>G p.N114S | Missense Mutation (SNP) | VAF 27/441 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, mutect2
- TRPC6 | c.2481A>C p.K827N | Missense Mutation (SNP) | VAF 27/369 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- USP7 | c.2739C>A p.D913E | Missense Mutation (SNP) | VAF 26/289 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2
- ZCCHC13 | c.353T>A p.L118H | Missense Mutation (SNP) | VAF 32/382 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.057); called by muse, mutect2
- DNER | c.2154T>C p.Y718= | Silent (SNP) | VAF 22/335 reads (7%) | catalogued as rs1187241512; called by muse, mutect2
- HINT3 | c.129C>T p.D43= | Silent (SNP) | VAF 8/251 reads (3%) | called by muse, mutect2
- IGHM | c.1203C>T p.S401= | Silent (SNP) | VAF 147/338 reads (43%) | catalogued as rs782590938; called by muse, mutect2, varscan2
- MAP1B | c.858C>T p.G286= | Silent (SNP) | VAF 54/234 reads (23%) | catalogued as rs777817448, COSV57099167; called by muse, mutect2, varscan2
- PCF11 | c.1041A>G p.K347= | Silent (SNP) | VAF 10/190 reads (5%) | called by muse, mutect2
- ROM1 | c.630T>C p.D210= | Silent (SNP) | VAF 20/191 reads (10%) | called by muse, mutect2, varscan2
- SARAF | c.666A>G p.G222= | Silent (SNP) | VAF 14/100 reads (14%) | called by mutect2, varscan2
- AC009053.1 | n.1461C>T | RNA (SNP) | VAF 24/412 reads (6%) | catalogued as rs776243285; called by muse, mutect2
- ADCY1 | c.1605+2141C>A | Intron (SNP) | VAF 44/245 reads (18%) | called by muse, mutect2, varscan2
- EIF2B4 | c.499-18T>C | Intron (SNP) | VAF 14/348 reads (4%) | called by muse, mutect2
- LINC00482 | n.1200G>T | RNA (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- LRFN5 | c.*40A>G | 3'UTR (SNP) | VAF 18/258 reads (7%) | catalogued as COSV99984225; called by muse, mutect2
- MIR519D | n.29C>T | RNA (SNP) | VAF 38/380 reads (10%) | catalogued as rs550303151; called by muse, mutect2
- RRP7A | c.217-150A>G | Intron (SNP) | VAF 26/233 reads (11%) | catalogued as rs1487915585; called by muse, mutect2, varscan2
- SLITRK5 | c.-9+757T>C | Intron (SNP) | VAF 56/360 reads (16%) | called by muse, mutect2, varscan2
- SSR1 | c.*42C>G | 3'UTR (SNP) | VAF 36/260 reads (14%) | called by muse, mutect2, varscan2
